Somatic mutation profile of tumor specimen TARGET-10-PARBNY-09A (aliquot TARGET-10-PARBNY-09A-01D) from TARGET case TARGET-10-PARBNY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (991 days).
Specimen TARGET-10-PARBNY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6791996a-d708-48d4-a981-b82866f9044e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBNY-10A (Blood Derived Normal), aliquot TARGET-10-PARBNY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21189c2e-7d4d-48e6-83c8-1d96f01bfe26

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Intron 1, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN8 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs763781240; called by muse, mutect2, varscan2
- COL11A2 | c.4558C>T p.R1520C (on ENST00000341947 / NM_080680.3; = p.R1413C on NM_080679.2) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs934714603, COSV59494192; called by muse, mutect2, varscan2
- ZBED8 | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs763605230, COSV101283499; called by muse, mutect2, varscan2
- KMT2D | c.15124del p.A5042Pfs*9 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- LCAT | c.1021_1022insC p.V341Afs*26 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel*, varscan2
- SPAG9 | c.1370A>G p.Q457R (on ENST00000262013 / NM_001130528.3; = p.Q443R on NM_003971.6) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.365); called by muse, mutect2
- CRISP3 | c.576A>G p.K192= (on ENST00000371159 / NM_001368123.1; = p.K174= on NM_006061.4) | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- FAT1 | c.12804G>A p.L4268= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as rs1032269769; called by muse, mutect2
- ROBO1 | c.1125C>T p.T375= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs1346976977, COSV101458740; called by muse, mutect2, varscan2
- SPAG9 | c.1368G>A p.K456= (on ENST00000262013 / NM_001130528.3; = p.K442= on NM_003971.6) | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2
- LINC02145 | n.432G>A | RNA (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- REG3G | c.196-96G>A | Intron (SNP) | VAF 13/112 reads (12%) | catalogued as rs980163406; called by muse, mutect2, varscan2
